Gene-level copy-number profile of tumor specimen TCGA-YF-AA3L-01A from TCGA case TCGA-YF-AA3L, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 47.3 years (17,268 days).
Specimen TCGA-YF-AA3L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.97ac9cb7-dbd3-4ecd-a371-bbf8bcee89ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YF-AA3L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6fca7c5e-d5c2-44cc-8014-4d51f3ed360f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 40; copy number 2: 8,564; copy number 3: 18,165; copy number 4: 25,878; copy number 5: 3,328; copy number 6: 233; copy number 7: 772; copy number 8: 2,774.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YF-AA3L-01A-11D-A38F-01): tumor purity 0.91, ploidy 3.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–51,024,120, 63 genes (broad region; genes not listed).
- chr13:51,027,747–51,027,852, 1 gene: RNA5SP29.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 40. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
